HCMI case HCM-BROD-0236-C34 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6ae8e01b-bcff-44c1-ad03-b354aae0d7d5

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1968; Vital status: Dead; Days to death: 409 days (1.1 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; ICD-10 code: C79.3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: metastasis; Age at diagnosis: 48.4 years (17,670 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IV; AJCC pathologic T: T4; AJCC pathologic N: N2; AJCC pathologic M: M1b; AJCC pathologic stage: Stage IV; Tumor grade: GX; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: No; Sites of involvement: Brain, NOS.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 25 days.
   Treatment given: Treatment type: Stereotactic Radiosurgery; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 340 days; Days to treatment end: 363 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease.

Follow-up (4 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 0 days.
- Days to follow up: 325 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 325 days.
- Days to follow up: 409 days (1.1 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 391.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 67 kg; Height: 180 cm; BMI: 20.7.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0236-C34-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
  Slide HCM-BROD-0236-C34-06A-01-S1-HE: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 24; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 5.
  Slide HCM-BROD-0236-C34-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 15; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 4.
- Sample HCM-BROD-0236-C34-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
